Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7476, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7476-01A (Primary Tumor).

ADDENDUM DISCUSSION:

The neoplastic cells are consistently immunoreactive for p53 indicative astrocytic origin. Scattered MIB-1 reactive cells are present. In the majority of the specimen, a labeling index of 3.6% is calculated. However, there is one focus with higher proliferative activity and a labeling index of 7.1%. Whereas this higher value merits close follow-up, a classification of anaplastic is not warranted.

ADDENDUM DIAGNOSIS:

- 1, 2. LEFT TEMPORAL TUMOR, BIOPSY AND RESECTION:
WELL DIFFERENTIATED ASTROCYTOMA, WHO GRADE II.
- MIB-1 LABELING INDEX = 3.6% - 7.1%; SEE DESCRIPTION.

MICROSCOPIC DESCRIPTION:

1. Permanent section of the frozen section specimen 1 demonstrates a moderately hypercellular glial neoplasm that is composed primarily of cells resembling fibrillary and protoplasmic astrocytes. Prominent microcystic change is seen. Atypia is generally mild with only a rare, moderately atypical nucleus. No mitoses are seen and there is no microvascular proliferation or necrosis.
2. Less than 10% of the specimen demonstrates infiltrating low grade glioma with features as previously described. Definite oligodendroglioma differentiation is not seen. The vast majority of the specimen consists of acute hematoma and surgical packing material.

Source: NCI Genomic Data Commons file ab47f98d-fe55-499e-8fc1-353c94a57d06 (TCGA-HT-7476.8B010189-B14A-458F-98B9-8934205460FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).